Somatic mutation profile of tumor specimen C3L-08992-02 (aliquot CPT0498760007) from CPTAC case C3L-08992, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 69.1 years (25,231 days).
Specimen C3L-08992-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87cb10a3-2aeb-40b0-af1c-2c55376a86f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08992-32 (Blood Derived Normal), aliquot CPT0498900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0ab2783-2e20-4921-a237-637bdf754fec

The open-access MAF lists 113 somatic variants for this specimen: 79 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 30, Nonsense Mutation 3, Splice Region 2, Intron 2, RNA 1, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.10204G>A p.G3402R | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs143194909; called by muse, mutect2
- ANAPC5 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1555273379; called by muse, mutect2
- ANXA9 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs761180071; called by muse, mutect2, varscan2
- ATP10B | c.3221G>T p.G1074V | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59165831; called by muse, mutect2
- CAMLG | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs1194849257, COSV99777706; called by muse, mutect2
- CARMIL2 | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs977741967; called by muse, mutect2
- CECR2 | c.4204G>A p.G1402S (on ENST00000342247 / NM_001290047.2; = p.G1218S on NM_001290046.1) | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs778560536; called by muse, mutect2
- CEP41 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs546106020; called by muse, mutect2
- CLCNKA | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 44/554 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs898631803; called by muse, mutect2
- CRTAC1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 63/444 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs768231154, COSV54008138; called by muse, mutect2, varscan2
- CSMD3 | c.1471G>T p.E491* (on ENST00000297405 / NM_001363185.1; = p.E387* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 20/274 reads (7%) | catalogued as COSV52165514, COSV99844673; called by muse, mutect2
- DOCK10 | c.5123A>T p.K1708M | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99292749; called by muse, mutect2
- DPYSL2 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 13/384 reads (3%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as rs1028123682; called by muse, mutect2
- EFS | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313159510; called by muse, mutect2
- EPHA8 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 36/531 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187814118; called by muse, mutect2
- FAT3 | c.6359C>A p.T2120N | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs1450726327; called by muse, mutect2, varscan2
- FMN2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 81/400 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs539147063; called by muse, mutect2, varscan2
- GLT1D1 | c.366A>C p.Q122H | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.251); catalogued as COSV55888232; called by muse, mutect2, varscan2
- HHIPL2 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 76/518 reads (15%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs777088140, COSV100597141; called by muse, mutect2, varscan2
- HMBOX1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780120331; called by muse, mutect2
- KCNS2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 51/529 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs780101812; called by muse, mutect2
- KLRC3 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs768046359, COSV101122914, COSV67251385; called by muse, mutect2
- LRFN3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 51/494 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759676327, COSV55816924; called by muse, mutect2, varscan2
- LTBP4 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 58/598 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1435850746; called by muse, mutect2
- MAP2 | c.2709A>C p.K903N | Missense Mutation (SNP) | VAF 34/355 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52294101; called by muse, mutect2, varscan2
- MORC2 | c.1984G>A p.A662T (on ENST00000397641 / NM_001303256.3; = p.A600T on NM_014941.3) | Missense Mutation (SNP) | VAF 40/566 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs770714218, COSV53196388; called by muse, mutect2
- MSN | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 74/520 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1315877285, COSV64303733; called by muse, mutect2, varscan2
- MTFR1L | c.774G>A p.L258= | Splice Region (SNP) | VAF 22/224 reads (10%) | catalogued as COSV65353117; called by muse, mutect2
- MUC12 | c.12517G>A p.D4173N (on ENST00000379442; = p.D4030N on NM_001164462.1) | Missense Mutation (SNP) | VAF 35/1207 reads (3%) | SIFT deleterious (0.03); catalogued as rs1168948029; called by muse, mutect2
- NACC1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 30/613 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1311271497; called by muse, mutect2
- NAIF1 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs141755077; called by muse, mutect2
- NAV3 | c.5222C>T p.P1741L | Missense Mutation (SNP) | VAF 37/421 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148932437, COSV57090810, COSV57116543; called by muse, mutect2
- NCBP3 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV50112247; called by muse, mutect2
- OR51A4 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as rs1279887625; called by muse, mutect2
- PCDHGB1 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 38/483 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.029); catalogued as rs758290229, COSV53955864, COSV54007463; called by muse, mutect2
- PLEC | c.5633G>A p.R1878H (on ENST00000322810 / NM_201380.4; = p.R1768H on NM_000445.5) | Missense Mutation (SNP) | VAF 55/476 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.319); catalogued as rs782125424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PZP | c.4300A>C p.S1434R | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV54353742; called by muse, mutect2
- RADIL | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 44/656 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as rs761814946; called by muse, mutect2
- RBMS3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 40/581 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV56136170; called by muse, mutect2
- RFX2 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 38/500 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs763173797; called by muse, mutect2
- RIMBP2 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs370841973; called by muse, mutect2, varscan2
- SEMA5B | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); catalogued as rs1257264438; called by muse, mutect2
- SLC22A13 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 40/476 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201547069; called by muse, mutect2
- TAS2R60 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.286); catalogued as rs144039157, COSV60331685; called by muse, mutect2, varscan2
- YWHAB | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 14/468 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.868); catalogued as rs1190977283, COSV62303928; called by muse, mutect2
- ZNF470 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100401451, COSV57969635; called by muse, mutect2, varscan2
- ZNF470 | c.2010T>G p.I670M | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV100401410, COSV57970496; called by muse, mutect2
- ZNF646 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 84/461 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as rs767353514, COSV56211367; called by muse, mutect2, varscan2
- ABRAXAS2 | c.376_377insC p.V126Afs*27 | Frame Shift Ins (INS) | VAF 47/484 reads (10%) | called by mutect2, pindel
- ACOT8 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 64/433 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANP32D | c.243A>C p.E81D | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, mutect2
- AR | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 62/702 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- ARHGEF10 | c.1835C>T p.A612V (on ENST00000398564; = p.A587V on NM_014629.4) | Missense Mutation (SNP) | VAF 38/522 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATM | c.254C>G p.S85* | Nonsense Mutation (SNP) | VAF 55/339 reads (16%) | called by muse, mutect2, varscan2
- BANK1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.372); called by muse, mutect2
- CCDC6 | c.320A>G p.Q107R | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2
- CFP | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 106/748 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EZHIP | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 65/584 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FANCB | c.2166G>A p.R722= | Splice Region (SNP) | VAF 9/212 reads (4%) | called by muse, mutect2
- FOXO4 | c.161T>A p.L54Q | Missense Mutation (SNP) | VAF 101/733 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- GLP1R | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPR158 | c.2315A>G p.E772G | Missense Mutation (SNP) | VAF 16/556 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2
- KCNB1 | c.797A>C p.D266A | Missense Mutation (SNP) | VAF 71/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM7A | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 43/487 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.09); called by muse, mutect2
- KIF7 | c.1552A>T p.K518* | Nonsense Mutation (SNP) | VAF 22/323 reads (7%) | called by muse, mutect2
- LOX | c.110_118del p.A37_P39del | In Frame Del (DEL) | VAF 73/467 reads (16%) | called by mutect2, pindel, varscan2
- NCAM1 | c.1994G>C p.G665A (on ENST00000316851 / NM_181351.5; = p.G655A on NM_000615.7) | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR8H1 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA3 | c.2895G>C p.R965S | Missense Mutation (SNP) | VAF 62/368 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRPN | c.317T>A p.V106D | Missense Mutation (SNP) | VAF 28/515 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.325); called by muse, mutect2
- STARD9 | c.10679G>T p.G3560V | Missense Mutation (SNP) | VAF 42/384 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TBL1X | c.1612A>T p.N538Y | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TENM3 | c.5630G>A p.R1877Q | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2
- TGFBR1 | c.956del p.E319Gfs*16 | Frame Shift Del (DEL) | VAF 30/240 reads (13%) | called by mutect2, pindel, varscan2
- TKTL1 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM17 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- TRAM1L1 | c.1042A>T p.N348Y | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- VSIG4 | c.1015T>G p.F339V | Missense Mutation (SNP) | VAF 46/559 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2
- ZMYM1 | c.2501C>G p.A834G | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2
- ADAMTS10 | c.72C>T p.H24= | Silent (SNP) | VAF 32/399 reads (8%) | catalogued as rs1555742459; called by muse, mutect2
- ATP2A3 | c.955C>T p.L319= | Silent (SNP) | VAF 26/398 reads (7%) | catalogued as COSV59233509; called by muse, mutect2
- CNGB1 | c.3330C>T p.N1110= | Silent (SNP) | VAF 32/452 reads (7%) | catalogued as rs566102644, COSV51899189; ClinVar: uncertain significance; called by muse, mutect2
- CSF2RB | c.462G>A p.V154= | Silent (SNP) | VAF 49/525 reads (9%) | called by muse, mutect2
- DZIP1L | c.1824C>T p.P608= | Silent (SNP) | VAF 24/354 reads (7%) | catalogued as rs375252496, COSV59521978; called by muse, mutect2
- FAHD2A | c.231C>T p.L77= | Silent (SNP) | VAF 24/308 reads (8%) | catalogued as rs372626548; called by muse, mutect2
- GRHL3 | c.1848C>A p.V616= | Silent (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- KAT6B | c.5760G>A p.K1920= | Silent (SNP) | VAF 74/474 reads (16%) | called by muse, mutect2, varscan2
- KCNF1 | c.792C>T p.L264= | Silent (SNP) | VAF 49/685 reads (7%) | called by muse, mutect2
- KLK11 | c.705C>T p.S235= (on ENST00000594768 / NM_144947.3; = p.S203= on NM_006853.3) | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs1236203593; called by muse, mutect2
- NEFM | c.93G>A p.P31= | Silent (SNP) | VAF 48/562 reads (9%) | catalogued as COSV55332314; called by muse, mutect2
- NLN | c.726C>T p.T242= | Silent (SNP) | VAF 30/312 reads (10%) | catalogued as rs992470173; called by muse, mutect2
- NOTCH3 | c.924C>T p.G308= | Silent (SNP) | VAF 40/464 reads (9%) | catalogued as rs1043995; ClinVar: uncertain significance; called by muse, mutect2
- OGDHL | c.978G>A p.A326= | Silent (SNP) | VAF 50/317 reads (16%) | catalogued as rs1363941705; called by muse, mutect2, varscan2
- OR2T2 | c.360C>A p.A120= | Silent (SNP) | VAF 86/872 reads (10%) | called by muse, mutect2, varscan2
- POU4F3 | c.423C>T p.P141= | Silent (SNP) | VAF 36/536 reads (7%) | catalogued as rs140857174; called by muse, mutect2
- PPP4R3C | c.120G>T p.L40= | Silent (SNP) | VAF 49/370 reads (13%) | called by muse, mutect2, varscan2
- RHPN2 | c.522C>T p.Y174= | Silent (SNP) | VAF 26/336 reads (8%) | called by muse, mutect2
- RPRML | c.60C>T p.G20= | Silent (SNP) | VAF 47/399 reads (12%) | called by muse, mutect2, varscan2
- RYR1 | c.2658C>T p.I886= | Silent (SNP) | VAF 29/391 reads (7%) | catalogued as rs148094797; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- SLITRK5 | c.966T>A p.A322= | Silent (SNP) | VAF 16/496 reads (3%) | called by muse, mutect2
- SOBP | c.1764G>A p.K588= | Silent (SNP) | VAF 56/509 reads (11%) | called by muse, mutect2, varscan2
- SPDYE5 | c.966G>A p.P322= | Silent (SNP) | VAF 52/647 reads (8%) | catalogued as rs782181392; called by muse, mutect2
- STK3 | c.1080C>T p.S360= | Silent (SNP) | VAF 42/366 reads (11%) | catalogued as rs764933237; called by muse, mutect2
- TAF1A | c.780C>T p.L260= | Silent (SNP) | VAF 28/410 reads (7%) | called by muse, mutect2
- TSPOAP1 | c.2712C>T p.P904= | Silent (SNP) | VAF 48/468 reads (10%) | catalogued as rs371250340; called by muse, mutect2, varscan2
- TTN | c.10068T>G p.T3356= (on ENST00000591111; = p.T3310= on NM_003319.4) | Silent (SNP) | VAF 32/359 reads (9%) | catalogued as COSV60015355; called by muse, mutect2
- VCAN | c.4887G>A p.E1629= | Silent (SNP) | VAF 36/444 reads (8%) | catalogued as rs770060933; called by muse, mutect2
- WNT5A | c.540C>T p.G180= | Silent (SNP) | VAF 46/514 reads (9%) | catalogued as rs776147539, COSV52839558; called by muse, mutect2
- ZNF750 | c.1869G>A p.A623= | Silent (SNP) | VAF 62/552 reads (11%) | catalogued as rs1223059446; called by muse, mutect2, varscan2
- ARHGAP15 | c.384+7279G>A | Intron (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- CDH11 | c.-107A>G | 5'UTR (SNP) | VAF 35/316 reads (11%) | called by muse, mutect2, varscan2
- DCHS2 | n.1855C>G | RNA (SNP) | VAF 36/440 reads (8%) | called by muse, mutect2
- TRPS1 | c.2661+71759T>A | Intron (SNP) | VAF 39/255 reads (15%) | called by muse, mutect2, varscan2
